Somatic mutation profile of tumor specimen C3N-01510-02 (aliquot CPT0079650009) from CPTAC case C3N-01510, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 53.3 years (19,465 days).
Specimen C3N-01510-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64475565-e011-4d05-960d-60e7c92162ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01510-31 (Blood Derived Normal), aliquot CPT0080750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/576c3dd2-c6c9-429a-8a40-6490ca3c96a5

The open-access MAF lists 516 somatic variants for this specimen: 339 protein-altering or splice-affecting, 141 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 304, Silent 141, Intron 22, Nonsense Mutation 21, Frame Shift Del 6, RNA 4, 5'UTR 4, 3'UTR 4, Frame Shift Ins 3, 3'Flank 2, Splice Region 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 154/463 reads (33%) | hotspot (GDC flag); catalogued as COSV61375361; called by muse, mutect2, varscan2
- CTCF | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs968244943, COSV50461455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTCF | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | hotspot (GDC flag); catalogued as rs769948988, COSV50461776; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 61/133 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.1459C>T p.R487C (on ENST00000399959; = p.R488C on NM_001356.5) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs796052234, COSV101302534; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYRK1A | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as rs780441716, COSV58295398; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 25/31 reads (81%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 41/129 reads (32%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- SMAD6 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 141/378 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387907284, CM122372; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCB1 | c.992G>A p.R331H (on ENST00000263121; = p.R377H on NM_003073.5) | Missense Mutation (SNP) | VAF 325/855 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs387906812, CM122478, COSV51954090, COSV51954233, COSV51954740; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.2786G>A p.R929H (on ENST00000272895 / NM_173076.3; = p.R611H on NM_015657.3) | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755121638, COSV55948162; called by muse, mutect2, varscan2
- ABCA3 | c.4118C>T p.P1373L | Missense Mutation (SNP) | VAF 330/940 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs762214425, COSV57051913; called by muse, mutect2, varscan2
- ACER1 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 66/354 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as rs909462126, COSV56835258; called by muse, mutect2, varscan2
- ADAMTS7 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 366/821 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.184); catalogued as COSV101183031, COSV66306280; called by muse, mutect2, varscan2
- ADCY5 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs749651565; called by muse, mutect2, varscan2
- ADD2 | c.1951G>A p.G651R | Missense Mutation (SNP) | VAF 95/534 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781966159, COSV52462784; called by muse, mutect2, varscan2
- ADGRA1 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 173/379 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as rs745518464, COSV101658586, COSV101658628; called by muse, mutect2, varscan2
- ADGRB1 | c.2125G>A p.V709I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs536011231, COSV99075409; called by muse, mutect2
- ADORA1 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.17); catalogued as rs747849534; called by muse, mutect2, varscan2
- AHI1 | c.2921C>T p.T974M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373303895; called by muse, mutect2, varscan2
- ALDH1A2 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 83/196 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs765361183, COSV51077923; called by muse, mutect2, varscan2
- AMH | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 177/658 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.881); catalogued as rs146124583; called by muse, mutect2, varscan2
- AMIGO1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 117/321 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as rs748122059, COSV63990225; called by muse, mutect2, varscan2
- ANKRD44 | c.1084G>A p.G362R | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV99985433; called by muse, mutect2, varscan2
- ANO2 | c.2159C>T p.S720L (on ENST00000356134 / NM_001278597.3; = p.S724L on NM_001278596.3) | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs764183496, COSV59017542; called by muse, mutect2, varscan2
- APLP1 | c.424+1G>A p.X142_splice | Splice Site (SNP) | VAF 37/74 reads (50%) | catalogued as rs1224616284; called by muse, mutect2, varscan2
- ARHGAP19 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs554411827, COSV57393518; called by muse, mutect2, varscan2
- ARHGEF16 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 100/322 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as rs777307132, COSV65682676; called by muse, mutect2, varscan2
- ARRDC2 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 80/312 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs780715164; called by muse, mutect2, varscan2
- ASCC2 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 211/482 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1168685696; called by muse, varscan2
- ATP2B3 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 177/437 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs1441248349; called by muse, mutect2, varscan2
- ATP6V1H | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.42); catalogued as rs200564944; called by muse, mutect2, varscan2
- BARHL2 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 92/414 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs748652602; called by muse, mutect2, varscan2
- BEAN1 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 142/320 reads (44%) | catalogued as rs761750785; called by muse, mutect2
- BEST3 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 181/512 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766338045, COSV56993729, COSV56995604; called by muse, mutect2, varscan2
- BMP1 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 97/243 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751439911; called by muse, mutect2, varscan2
- BRAT1 | c.1087G>A p.G363S | Missense Mutation (SNP) | VAF 188/489 reads (38%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.694); catalogued as rs967919052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTRC | c.1781G>A p.R594H (on ENST00000370187 / NM_033637.4; = p.R558H on NM_003939.5) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.871); catalogued as rs141030727, COSV64581421, COSV64581735; called by muse, mutect2, varscan2
- C1QL4 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1162156820; called by muse, mutect2, varscan2
- C20orf27 | c.416G>A p.R139H (on ENST00000379772 / NM_001258429.2; = p.R164H on NM_001039140.3) | Missense Mutation (SNP) | VAF 81/297 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs746711207, COSV53925257; called by muse, mutect2, varscan2
- C2CD2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 26/476 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs971367704, COSV66855041; called by muse, mutect2
- CACNA1B | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 167/399 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.646); catalogued as rs768660275, COSV53115105; called by muse, mutect2, varscan2
- CACNA1F | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 91/233 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs782458308, COSV59907127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADM1 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1453245186, COSV59005301; called by muse, mutect2, varscan2
- CAMK2B | c.819C>T p.C273= | Splice Region (SNP) | VAF 19/95 reads (20%) | catalogued as rs774396408, COSV51659888; called by muse, mutect2, varscan2
- CBLB | c.2393C>T p.T798M | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as rs750014939; called by muse, mutect2, varscan2
- CCDC120 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 63/307 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs782029039, COSV64515194; called by muse, mutect2, varscan2
- CCL24 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 132/337 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.374); catalogued as rs1554533491, COSV56116282; called by muse, mutect2, varscan2
- CCNQ | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 158/392 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.724); catalogued as rs1557026096, COSV99367952; called by muse, mutect2, varscan2
- CD209 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs755645551; called by muse, mutect2, varscan2
- CDK11A | c.1090C>T p.R364W (on ENST00000378633 / NM_001313896.2; = p.R361W on NM_024011.4) | Missense Mutation (SNP) | VAF 126/332 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.93); catalogued as rs1233263675; called by mutect2, varscan2
- CDK11B | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 106/1032 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.968); catalogued as rs1191642385; called by muse, mutect2
- CECR2 | c.1078G>A p.E360K (on ENST00000342247 / NM_001290047.2; = p.E197K on NM_001290046.1) | Missense Mutation (SNP) | VAF 99/265 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs536063005; called by muse, mutect2, varscan2
- CFAP43 | c.3865C>T p.R1289C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs778690270, COSV63853189; called by muse, mutect2, varscan2
- CHD8 | c.4310G>A p.R1437H (on ENST00000646647 / NM_001170629.2; = p.R1158H on NM_020920.4) | Missense Mutation (SNP) | VAF 78/217 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs1176349106; called by muse, mutect2, varscan2
- CMSS1 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs751990212; called by muse, mutect2
- CNOT1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.332); catalogued as COSV57780922; called by muse, mutect2, varscan2
- COL7A1 | c.4540C>T p.R1514C | Missense Mutation (SNP) | VAF 221/589 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1170025132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPNE6 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs778414373; called by muse, mutect2, varscan2
- CRACD | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 208/556 reads (37%) | catalogued as COSV51718686; called by muse, mutect2, varscan2
- CROCC2 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 121/262 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs772318588; called by muse, mutect2, varscan2
- CRYBG3 | c.3485C>T p.A1162V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as rs979517310; called by muse, mutect2, varscan2
- CSMD1 | c.5881G>A p.V1961I (on ENST00000520002; = p.V1960I on NM_033225.6) | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750472120, COSV59388624; called by muse, mutect2, varscan2
- CTNNA2 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs376745664; called by muse, mutect2
- CTR9 | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs1391585643, COSV63728784; called by muse, mutect2, varscan2
- DCAF12L2 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 62/259 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63582337; called by muse, mutect2, varscan2
- DCHS2 | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 89/205 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763954452; called by muse, mutect2, varscan2
- DDX54 | c.2266G>A p.G756S | Missense Mutation (SNP) | VAF 105/292 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1258853655; called by muse, mutect2, varscan2
- DENND1C | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 100/394 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs770406894; called by muse, mutect2, varscan2
- DIPK2B | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 124/314 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.728); catalogued as COSV100933462; called by muse, mutect2, varscan2
- DISP3 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53828675, COSV53837760; called by muse, mutect2, varscan2
- DLGAP2 | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370388753; called by muse, mutect2, varscan2
- DLGAP2 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 83/157 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs1418799410, COSV101421543; called by muse, mutect2, varscan2
- DLGAP2 | c.2875G>A p.V959I | Missense Mutation (SNP) | VAF 11/266 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (0.977); catalogued as rs760733915; called by muse, mutect2
- DNAH8 | c.5867G>A p.R1956H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139579198, COSV59427962; called by muse, mutect2, varscan2
- DOCK3 | c.5366G>A p.R1789H | Missense Mutation (SNP) | VAF 116/336 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as rs777938666, COSV99810765; called by muse, mutect2, varscan2
- DRD3 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs201759000; called by muse, mutect2, varscan2
- DUXA | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs748002224, COSV101617126, COSV73729482; called by muse, mutect2, varscan2
- DYSF | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 161/449 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs759065714, COSV50509422; called by muse, mutect2, varscan2
- EBF1 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 116/311 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58193946; called by muse, mutect2, varscan2
- EFR3A | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as rs764347591, COSV99602292; called by muse, mutect2, varscan2
- EFTUD2 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV53655180; called by muse, mutect2, varscan2
- EML5 | c.2356C>T p.R786C | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs375727661; called by muse, mutect2, varscan2
- EPHB2 | c.2305C>T p.R769C (on ENST00000400191 / NM_001309193.2; = p.R770C on NM_004442.7) | Missense Mutation (SNP) | VAF 147/372 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367548936; called by muse, mutect2, varscan2
- EPS8L3 | c.1055C>G p.S352C | Missense Mutation (SNP) | VAF 121/318 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV62609120; called by muse, mutect2, varscan2
- ESPNL | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 164/356 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.221); catalogued as rs772136363, COSV58035443; called by muse, mutect2, varscan2
- FAM234B | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1274841247, COSV99546146; called by muse, mutect2, varscan2
- FCGBP | c.10975G>A p.G3659R | Missense Mutation (SNP) | VAF 162/445 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs922381430; called by muse, mutect2, varscan2
- FGFR3 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 166/390 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as rs746415876, COSV99601350; called by muse, mutect2, varscan2
- FLNB | c.4282G>A p.G1428S | Missense Mutation (SNP) | VAF 171/456 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747673269; called by muse, mutect2, varscan2
- FOXA3 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 171/500 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444890389, COSV56215273; called by muse, mutect2, varscan2
- FOXO4 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); catalogued as rs752656715, COSV58576544; called by muse, mutect2, varscan2
- GAN | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs772385806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GARNL3 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 38/81 reads (47%) | catalogued as COSV59225848; called by muse, mutect2, varscan2
- GJB5 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 110/290 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.124); catalogued as rs373607646; called by muse, mutect2, varscan2
- GLP2R | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 103/442 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs146242583, COSV99301581; called by muse, mutect2, varscan2
- GLT6D1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs867118146, COSV65627291; called by muse, mutect2, varscan2
- GNA11 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 92/197 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767809613, COSV50019275, COSV99313174; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 59/187 reads (32%) | catalogued as rs776791261; called by muse, mutect2, varscan2
- GPAM | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs185462411, CM109861, COSV62080668; called by muse, mutect2, varscan2
- GRID2IP | c.3122C>T p.T1041M | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs969577691; called by muse, mutect2, varscan2
- H3-4 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 193/489 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.642); catalogued as COSV64210988; called by muse, mutect2, varscan2
- HDAC9 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs755314928; called by muse, mutect2, varscan2
- HECW2 | c.4628G>A p.R1543H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs781523022, COSV53672898; called by muse, mutect2
- HEPACAM | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs367663549; called by muse, mutect2, varscan2
- HERC1 | c.5947C>T p.R1983C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs781450433, COSV101496677; called by muse, mutect2, varscan2
- HERC2 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1464651314; called by muse, mutect2, varscan2
- HOXA1 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV58029220; called by muse, mutect2, varscan2
- HSF5 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs763655733, COSV100051270, COSV60201683; called by muse, mutect2, varscan2
- HSPA2 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 230/567 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55969833; called by muse, mutect2, varscan2
- HUS1B | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs898043016; called by muse, mutect2, varscan2
- HUWE1 | c.3938G>A p.R1313Q | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as rs1556979918; called by muse, mutect2, varscan2
- HYDIN | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753825612, COSV55482951; called by muse, mutect2, varscan2
- IGBP1P2 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); catalogued as rs568899194, COSV53621351; called by muse, mutect2, varscan2
- IGKV6D-21 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs771723923; called by mutect2, varscan2
- IL16 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 165/503 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs780472079, COSV57263126; called by muse, mutect2, varscan2
- IL22RA1 | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs201130676; called by muse, mutect2, varscan2
- INF2 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs1288069245; called by muse, mutect2
- INIP | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs762288543; called by muse, mutect2, varscan2
- IQCA1 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs765152475, COSV54498921; called by muse, mutect2, varscan2
- ITGA5 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 118/299 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.711); catalogued as rs773645556; called by muse, mutect2, varscan2
- ITGB3 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 76/205 reads (37%) | catalogued as rs758633284, CM109159; called by muse, mutect2, varscan2
- ITPR3 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as rs1370675904; called by muse, mutect2, varscan2
- JADE1 | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs867517017, COSV56908212; called by muse, mutect2, varscan2
- JAG2 | c.2980G>A p.G994R | Missense Mutation (SNP) | VAF 337/846 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as rs761595269, COSV59313942; called by muse, mutect2, varscan2
- JMJD4 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 179/1005 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs372699883; called by muse, mutect2, varscan2
- KALRN | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 89/262 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.835); catalogued as rs1162252325, COSV53779035; called by muse, mutect2, varscan2
- KCNA4 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 122/282 reads (43%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1221664561, COSV60253620; called by muse, varscan2
- KCNG4 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 183/469 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1255121485; called by muse, mutect2, varscan2
- KCNK10 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs777722776; called by muse, mutect2, varscan2
- KEL | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 152/391 reads (39%) | catalogued as rs61729045, CM078483; called by muse, mutect2, varscan2
- KIF12 | c.952C>T p.R318W (on ENST00000640217; = p.R180W on NM_138424.1) | Missense Mutation (SNP) | VAF 108/412 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs147234281; called by muse, mutect2, varscan2
- KLHL3 | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1367184898, COSV59057444; called by muse, mutect2, varscan2
- KLHL34 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 193/446 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV65278678; called by muse, mutect2, varscan2
- KMT2C | c.12571G>A p.A4191T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs376118166; called by muse, mutect2, varscan2
- KRT72 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756736404; called by muse, mutect2, varscan2
- LATS1 | c.1979G>A p.R660H | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99485703; called by mutect2, varscan2
- LHB | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 222/900 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); catalogued as rs1167086712; called by muse, mutect2, varscan2
- LIMK1 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 104/290 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs544200500, COSV100283376; called by muse, mutect2, varscan2
- LOXL3 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.328); catalogued as rs753208381; called by muse, mutect2
- LRCH4 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 206/527 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.397); catalogued as rs753151554, COSV59644592; called by muse, mutect2, varscan2
- LRP1 | c.13396G>A p.V4466M | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs530070761; called by muse, mutect2, varscan2
- LRRC27 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 102/275 reads (37%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs780399858; called by muse, mutect2, varscan2
- LRRC36 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs760615167; called by muse, varscan2
- LSG1 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs373170652; called by muse, mutect2, varscan2
- MAGEL2 | c.3430C>T p.R1144W | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.555); catalogued as rs1170449979, COSV58569210, COSV58569511; called by muse, mutect2, varscan2
- MAMDC4 | c.3014G>A p.R1005H (on ENST00000445819; = p.R926H on NM_206920.3) | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs756252473; called by muse, mutect2, varscan2
- MAPK12 | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 321/852 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747209953, COSV53132439; called by muse, mutect2, varscan2
- MAPK7 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1234097307; called by muse, mutect2, varscan2
- MICAL3 | c.3755C>T p.T1252M | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.074); catalogued as rs779015980, COSV101490855; called by muse, varscan2
- MLC1 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 269/672 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs370132302; called by muse, mutect2, varscan2
- MPP3 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 259/652 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs756653425; called by muse, mutect2, varscan2
- MTUS1 | c.2003G>A p.G668D | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1451650754; called by muse, mutect2, varscan2
- MVD | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 183/445 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs772577920, COSV99964924; called by muse, mutect2, varscan2
- MX1 | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 13/334 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.938); catalogued as rs1345167441; called by muse, mutect2
- MYCBP2 | c.12911G>A p.R4304Q (on ENST00000357337; = p.R4342Q on NM_015057.5) | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1403360465, COSV100632457; called by muse, mutect2, varscan2
- MYCBPAP | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as rs763346426; called by muse, mutect2, varscan2
- MYOM2 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 147/414 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs570741458; called by muse, mutect2, varscan2
- NALCN | c.2579C>T p.A860V | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs186621340, COSV51922453, COSV99216417; called by muse, mutect2, varscan2
- NEFL | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 372/938 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55336660; called by muse, mutect2, varscan2
- NELFB | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.992); catalogued as rs745670214; called by muse, mutect2, varscan2
- NINJ1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 91/391 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs771785987, COSV64922684; called by muse, mutect2, varscan2
- NLRP7 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 228/594 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.812); catalogued as rs374089788; called by muse, mutect2, varscan2
- NOL6 | c.2477G>A p.R826H | Missense Mutation (SNP) | VAF 107/274 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs369849073, COSV99955216; called by muse, mutect2, varscan2
- NR4A2 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1362146401; called by muse, mutect2, varscan2
- NUTM2A | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 234/394 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs776861482; called by mutect2, varscan2
- NYAP2 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 66/166 reads (40%) | catalogued as rs1344227560; called by muse, mutect2, varscan2
- OBSCN | c.6944G>A p.R2315Q | Missense Mutation (SNP) | VAF 194/489 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as rs374417116, COSV52759375; called by muse, mutect2, varscan2
- OCM | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as rs755114818, COSV54194154; called by muse, mutect2, varscan2
- OR13G1 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as rs200763482, COSV100687494, COSV62943805; called by muse, mutect2, varscan2
- OR1D2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 100/267 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs139391156; called by muse, mutect2, varscan2
- OR2T33 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 222/900 reads (25%) | catalogued as rs1396360611, COSV100531888; called by muse, varscan2
- OR6B3 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 183/431 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs765762579, COSV60116264; called by muse, mutect2, varscan2
- PCDHA1 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 280/704 reads (40%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.014); catalogued as COSV65374644; called by muse, mutect2, varscan2
- PCDHA2 | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 163/441 reads (37%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.003); catalogued as rs1554120396, COSV65369368; called by muse, mutect2, varscan2
- PCDHA9 | c.2036C>T p.S679L | Missense Mutation (SNP) | VAF 28/452 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as rs782447188, COSV104429944; called by muse, mutect2
- PCDHA9 | c.2321C>T p.P774L | Missense Mutation (SNP) | VAF 122/150 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs543112905; called by muse, mutect2, varscan2
- PCDHB15 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 230/580 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as COSV50858209; called by muse, mutect2, varscan2
- PCDHB5 | c.1678G>A p.V560M | Missense Mutation (SNP) | VAF 408/1602 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs574506353, COSV50653565; called by muse, mutect2, varscan2
- PCDHGA11 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.022); catalogued as rs886758924, COSV53893318; called by muse, mutect2, varscan2
- PCDHGB1 | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 261/686 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.313); catalogued as COSV53902592; called by muse, mutect2, varscan2
- PDIA5 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs774726526, COSV60249034; called by muse, mutect2, varscan2
- PDZD8 | c.2977C>T p.R993W | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs749964132; called by muse, mutect2, varscan2
- PHKA2 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 119/337 reads (35%) | catalogued as rs760585193, CM078766, COSV66053233; called by muse, mutect2, varscan2
- PIEZO1 | c.7235G>A p.R2412Q | Missense Mutation (SNP) | VAF 152/419 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs553201091; called by muse, mutect2, varscan2
- PIGV | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 99/243 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs148135928; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3AP1 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 84/228 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.289); catalogued as rs760105346, COSV59531415; called by muse, mutect2, varscan2
- PLK4 | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs749534278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA4 | c.3425C>T p.P1142L | Missense Mutation (SNP) | VAF 156/425 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753895846; called by muse, mutect2, varscan2
- PNN | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as rs546480407, COSV53766424; called by muse, mutect2, varscan2
- POLR2E | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 145/310 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs1287704982, COSV99297635; called by muse, mutect2, varscan2
- PPFIA4 | c.1462C>T p.R488C (on ENST00000447715; = p.R463C on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs770786407; called by muse, mutect2, varscan2
- PPM1E | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.052); catalogued as rs771159498, COSV57572616, COSV57574700; called by muse, mutect2, varscan2
- PRKDC | c.5447G>A p.R1816H | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs746172040, COSV58047665; called by muse, mutect2, varscan2
- PRSS23 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs544759235; called by muse, mutect2, varscan2
- PSMB5 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 94/391 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as rs1035802892, COSV57801142; called by muse, mutect2, varscan2
- PTK2B | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 175/702 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774798724, COSV57758578; called by muse, mutect2, varscan2
- PTPN13 | c.5594T>C p.I1865T (on ENST00000411767 / NM_080683.3; = p.I1846T on NM_006264.3) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs780636946; called by muse, mutect2, varscan2
- PTPRS | c.5401C>T p.R1801C | Missense Mutation (SNP) | VAF 104/293 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs773706905, COSV53628810; called by muse, mutect2, varscan2
- PXDNL | c.2366G>A p.R789H | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs1243029604, COSV62492059; called by muse, mutect2, varscan2
- PXK | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV57089658; called by muse, mutect2, varscan2
- RALGPS1 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs755963750; called by muse, mutect2, varscan2
- RCCD1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as rs139606108; called by muse, mutect2, varscan2
- RGL2 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 81/235 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.735); catalogued as rs182884865, COSV65842130; called by muse, mutect2, varscan2
- RNF121 | c.762-1G>A p.X254_splice | Splice Site (SNP) | VAF 64/164 reads (39%) | catalogued as COSV52622231; called by muse, mutect2, varscan2
- RNFT2 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 128/301 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs374408722; called by muse, mutect2, varscan2
- RSPH10B | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 72/384 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs145755299; called by muse, mutect2, varscan2
- RTN2 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 449/1118 reads (40%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.015); catalogued as rs745409162, COSV55592360; ClinVar: benign; called by muse, mutect2, varscan2
- RYR1 | c.6730C>T p.R2244W | Missense Mutation (SNP) | VAF 358/990 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs772753793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.10063C>T p.R3355W (on ENST00000389232; = p.R3356W on NM_001036.6) | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755340876, COSV66805329; called by muse, mutect2, varscan2
- SASH1 | c.159C>T p.D53= | Splice Region (SNP) | VAF 74/182 reads (41%) | catalogued as rs758083632; ClinVar: likely benign; called by muse, mutect2, varscan2
- SAT1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63380905; called by muse, mutect2, varscan2
- SBK2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.227); catalogued as rs1364680244; called by muse, mutect2, varscan2
- SCARA5 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as rs1229527055, COSV57278532; called by muse, mutect2, varscan2
- SCN5A | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as rs752130196, CM154975, COSV100351259; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCYL1 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399523797, COSV54211023; called by muse, mutect2, varscan2
- SDR42E1 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as rs200329125, COSV100200707; called by muse, mutect2, varscan2
- SEMA4B | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 175/499 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772058869, COSV60173535; called by muse, mutect2, varscan2
- SETD1A | c.4196G>A p.R1399Q | Missense Mutation (SNP) | VAF 122/309 reads (39%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as rs1266448341; called by muse, mutect2, varscan2
- SH3RF3 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 137/748 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs141684240, COSV100512458; called by muse, mutect2, varscan2
- SHOX2 | c.430C>T p.R144W (on ENST00000441443 / NM_006884.3; = p.R168W on NM_003030.4) | Missense Mutation (SNP) | VAF 247/711 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67464263; called by muse, mutect2, varscan2
- SHPK | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 232/608 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs886673703; called by muse, mutect2, varscan2
- SIAE | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 110/285 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs972604088, COSV52516207; called by muse, mutect2, varscan2
- SIGLEC7 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.302); catalogued as rs368230574, COSV58315269; called by muse, mutect2
- SLC11A1 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 106/243 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777161870, COSV99261812, COSV99262535; called by muse, mutect2, varscan2
- SLC23A1 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 187/517 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs1390139377, COSV62296558; called by muse, mutect2, varscan2
- SLC26A5 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs745378351, COSV100100102; called by muse, mutect2, varscan2
- SLC37A3 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs778761904, COSV100405768; called by muse, mutect2, varscan2
- SNAP91 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52115155; called by muse, mutect2, varscan2
- SPATA31D1 | c.2891G>A p.R964H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.92); catalogued as rs367962212, COSV61199548; called by muse, mutect2, varscan2
- SPATA4 | c.643del p.L215Ffs*9 | Frame Shift Del (DEL) | VAF 30/90 reads (33%) | catalogued as rs1228689676; called by mutect2, pindel, varscan2
- SPEG | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 348/752 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs534977101, COSV56672606; called by muse, mutect2, varscan2
- SPTLC2 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as COSV99377483; called by muse, mutect2, varscan2
- STIL | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143587840; called by muse, mutect2, varscan2
- STK11IP | c.2371C>T p.R791* | Nonsense Mutation (SNP) | VAF 106/527 reads (20%) | catalogued as rs755470447; called by muse, mutect2, varscan2
- TACC2 | c.6041G>A p.R2014H (on ENST00000334433; = p.R92H on NM_006997.4) | Missense Mutation (SNP) | VAF 90/280 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs370799288; called by muse, mutect2, varscan2
- TAF1 | c.2545C>T p.R849C (on ENST00000373790 / NM_138923.4; = p.R870C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52109893; called by muse, mutect2, varscan2
- TBC1D10C | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 285/731 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1344791009, COSV100408198; called by muse, mutect2, varscan2
- TCTEX1D4 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 95/243 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs767451085; called by muse, mutect2, varscan2
- TENM4 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 198/476 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs1410637100; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2533G>A p.A845T | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs139792932, COSV99305007; called by muse, mutect2, varscan2
- TGM6 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 324/850 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs150088385; ClinVar: benign; called by muse, mutect2, varscan2
- THBS3 | c.2747G>A p.R916H | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140469044; called by muse, mutect2, varscan2
- TMEM164 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 170/422 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.042); catalogued as COSV99912158; called by muse, mutect2, varscan2
- TMEM250 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 133/322 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.951); catalogued as rs1297565329, COSV69307415; called by muse, varscan2
- TNFSF15 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs889534030, COSV65011132; called by muse, mutect2, varscan2
- TNS2 | c.682G>A p.V228I (on ENST00000314250 / NM_170754.4; = p.V238I on NM_015319.2) | Missense Mutation (SNP) | VAF 139/409 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs763199154; called by muse, mutect2, varscan2
- TNXB | c.4951G>A p.V1651M (on ENST00000647633; = p.V1404M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 314/799 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs766110850, COSV64478196; called by muse, mutect2, varscan2
- TOLLIP | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 78/215 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747426885; called by muse, mutect2, varscan2
- TRABD | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 66/293 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); catalogued as rs1324448288; called by muse, mutect2, varscan2
- TRAPPC5 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 118/312 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758609320; called by muse, mutect2, varscan2
- TRGV5 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs773521525; called by muse, mutect2, varscan2
- TRIM55 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs372993762, COSV52543139; called by muse, mutect2, varscan2
- TRMT61A | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 100/205 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.595); catalogued as rs765359264; called by muse, mutect2
- TRPM6 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1316180378; called by muse, mutect2, varscan2
- TTC38 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as rs372817703; called by muse, mutect2, varscan2
- TULP2 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 102/469 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.054); catalogued as rs1246736038, COSV55476875; called by muse, mutect2, varscan2
- TULP4 | c.3086G>A p.R1029Q | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs548116504; called by muse, mutect2, varscan2
- UBA1 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 157/361 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs199512751; called by muse, mutect2, varscan2
- UBR5 | c.3673C>T p.R1225W | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1258193278; called by muse, mutect2, varscan2
- ULK1 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 138/631 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs192583536, COSV58857951, COSV58859680; called by muse, mutect2, varscan2
- UNC5D | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs1334662855, COSV54772780, COSV54774766; called by muse, mutect2, varscan2
- USP19 | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 62/217 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs769311246; called by muse, mutect2, varscan2
- USP47 | c.2392G>A p.E798K (on ENST00000399455 / NM_001372095.1; = p.E710K on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.051); catalogued as rs1475032599, COSV60467086; called by muse, mutect2, varscan2
- WDR47 | c.2368C>T p.R790C (on ENST00000369962 / NM_001142551.2; = p.R791C on NM_014969.5) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs1158456288, COSV63057444; called by muse, mutect2, varscan2
- WDR90 | c.4213G>A p.V1405M | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372929238; called by muse, mutect2, varscan2
- WNK4 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 307/802 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53821945; called by muse, mutect2, varscan2
- XIRP1 | c.2453G>A p.R818Q | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs145488377; called by muse, mutect2, varscan2
- XRRA1 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as rs773580583, COSV58496025; called by muse, mutect2, varscan2
- ZBTB20 | c.361G>A p.V121M (on ENST00000474710 / NM_001164342.2; = p.V48M on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 180/465 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61844931; called by muse, mutect2, varscan2
- ZC3H13 | c.2290C>T p.R764W | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs779706341, COSV54457033; called by muse, mutect2, varscan2
- ZCWPW1 | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs369980465, COSV52199755; called by muse, mutect2, varscan2
- ZDBF2 | c.5035C>T p.R1679* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as rs559177241, COSV65623385; called by muse, mutect2, varscan2
- ZDHHC14 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 233/620 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.969); catalogued as rs768141598; called by muse, mutect2, varscan2
- ZFHX2 | c.7609G>A p.A2537T | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs1205118758; called by muse, mutect2, varscan2
- ZFPM1 | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 160/374 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs747907787, COSV60321042; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs147008651, COSV56272824; called by muse, mutect2, varscan2
- ZNF22 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as rs201002672; called by muse, mutect2, varscan2
- ZNF236 | c.2423C>T p.T808M | Missense Mutation (SNP) | VAF 32/558 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as rs754057667, COSV53496392; called by muse, mutect2
- ZNF250 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs750606892; called by muse, mutect2, varscan2
- ZNF263 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs371017559; called by muse, mutect2, varscan2
- ZNF41 | c.1822G>A p.V608I | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs767026141; called by muse, mutect2, varscan2
- ZNF513 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 119/246 reads (48%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.716); catalogued as rs1232309060; called by muse, mutect2, varscan2
- ZNF540 | c.843dup p.S282* | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | catalogued as rs757107073; called by mutect2, varscan2
- ZNF813 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.894); catalogued as rs199775956; called by muse, mutect2, varscan2
- ADCY1 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ADCY6 | c.1805T>A p.M602K | Missense Mutation (SNP) | VAF 140/325 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- AKR1C1 | c.303del p.R101Sfs*3 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel
- AQP3 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ARHGEF17 | c.2105C>A p.T702K | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGEF26 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 136/349 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP8A2 | c.3389G>A p.R1130H | Missense Mutation (SNP) | VAF 127/555 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- BCL11A | c.1045G>A p.G349S (on ENST00000335712 / NM_001365609.1; = p.G383S on NM_018014.4) | Missense Mutation (SNP) | VAF 247/750 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTBD11 | c.2465C>T p.T822I (on ENST00000280758 / NM_001018072.2; = p.T359I on NM_001017523.2) | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- C2orf81 | c.1435G>A p.G479S | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- C4orf54 | c.3217C>A p.Q1073K | Missense Mutation (SNP) | VAF 122/281 reads (43%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- CCDC117 | c.690del p.Y231Ifs*10 | Frame Shift Del (DEL) | VAF 30/84 reads (36%) | called by mutect2, pindel, varscan2
- CCDC171 | c.700dup p.M234Nfs*3 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | called by mutect2, pindel
- CCNB3 | c.3685G>A p.V1229M | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- CEBPZ | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2, varscan2
- CHD5 | c.3532G>A p.G1178S | Missense Mutation (SNP) | VAF 130/413 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTDSPL | c.572G>A p.R191Q (on ENST00000273179 / NM_001008392.2; = p.R180Q on NM_005808.3) | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CTSH | c.517_518dup p.Q174Pfs*56 | Frame Shift Ins (INS) | VAF 152/441 reads (34%) | called by mutect2, pindel, varscan2
- DCAF1 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- DCLK2 | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DEPDC1 | c.623A>G p.E208G | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DNAJB5 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 31/790 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2
- DUSP22 | c.54A>C p.K18N | Missense Mutation (SNP) | VAF 65/281 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- FAM180B | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 67/296 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GABBR1 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 301/775 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- GID8 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 194/464 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- GPRIN1 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 107/254 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GSG1 | c.911G>A p.S304N (on ENST00000651961 / NM_001080555.4; = p.S268N on NM_153823.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- HMGCR | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- HMGN4 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- IGDCC4 | c.2980G>A p.A994T | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, varscan2
- INPP4B | c.2669_2670del p.L890Qfs*33 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- IRX6 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 91/213 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIR3DL1 | c.1105del p.N369Mfs*4 | Frame Shift Del (DEL) | VAF 38/100 reads (38%) | called by mutect2, varscan2
- MAPK3 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MBTPS2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAK1 | c.1428del p.I476Mfs*23 | Frame Shift Del (DEL) | VAF 4/50 reads (8%) | called by mutect2, pindel
- PCDHB5 | c.1975G>A p.V659M | Missense Mutation (SNP) | VAF 384/1032 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PHF20L1 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- POTEF | c.1154A>T p.E385V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- RAD51AP1 | c.383_384insGTT p.H128delinsQF (on ENST00000228843 / NM_001130862.2; = p.H111delinsQF on NM_006479.5) | In Frame Ins (INS) | VAF 5/51 reads (10%) | called by mutect2, pindel
- RBM10 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 283/1231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- RTL3 | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SAMD1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 99/305 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- SETDB1 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMEM151A | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); called by muse, mutect2
- TRIM24 | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TRPC7 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- TSSK6 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TTN | c.16944C>A p.Y5648* (on ENST00000591111; = p.Y4721* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- UBE4B | c.1954G>A p.E652K (on ENST00000343090 / NM_001105562.3; = p.E523K on NM_006048.5) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.594); called by muse, varscan2
- WNT5A | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2
- ZBTB8B | c.1130G>C p.R377T | Missense Mutation (SNP) | VAF 123/295 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ABCF1 | c.2118G>A p.T706= (on ENST00000326195 / NM_001025091.2; = p.T668= on NM_001090.3) | Silent (SNP) | VAF 179/436 reads (41%) | catalogued as rs770543929; called by muse, mutect2, varscan2
- ABHD17A | c.363C>T p.A121= (on ENST00000292577 / NM_001130111.2; = p.A172= on NM_031213.4) | Silent (SNP) | VAF 219/482 reads (45%) | catalogued as rs757073884, COSV51749821; called by muse, mutect2, varscan2
- ALDH1L2 | c.927G>A p.T309= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs200155435; called by muse, mutect2
- ANPEP | c.1056C>T p.G352= | Silent (SNP) | VAF 142/342 reads (42%) | catalogued as rs769555661, COSV104410831; called by muse, mutect2, varscan2
- ARFIP2 | c.285C>T p.I95= | Silent (SNP) | VAF 62/156 reads (40%) | catalogued as rs551813312, COSV54446058; called by muse, mutect2, varscan2
- ARHGEF18 | c.2022C>T p.Y674= (on ENST00000359920 / NM_001130955.2; = p.Y570= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 148/319 reads (46%) | catalogued as rs374851624; called by muse, mutect2, varscan2
- ARL13A | c.165G>A p.S55= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as rs758563253, COSV65880051, COSV65880325; called by muse, mutect2, varscan2
- ASB2 | c.690C>T p.A230= | Silent (SNP) | VAF 115/310 reads (37%) | catalogued as rs146056951; called by muse, mutect2, varscan2
- ASB4 | c.750C>T p.D250= | Silent (SNP) | VAF 130/467 reads (28%) | catalogued as rs144658082; called by muse, mutect2, varscan2
- ASCC2 | c.1761C>T p.Y587= | Silent (SNP) | VAF 172/469 reads (37%) | called by muse, varscan2
- ASCL4 | c.87C>T p.P29= | Silent (SNP) | VAF 236/584 reads (40%) | catalogued as rs1405492344, COSV60817385; called by muse, mutect2, varscan2
- ATAD5 | c.5016C>T p.Y1672= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs770889957, COSV58972642; called by muse, mutect2, varscan2
- ATP10B | c.2904G>A p.K968= | Silent (SNP) | VAF 63/137 reads (46%) | called by muse, mutect2, varscan2
- ATXN2L | c.2346G>A p.T782= | Silent (SNP) | VAF 44/442 reads (10%) | catalogued as rs762557718, COSV100294054, COSV100294159, COSV57372588; called by muse, mutect2
- B3GNT5 | c.207G>A p.A69= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs201133824; called by muse, mutect2, varscan2
- BRSK1 | c.1011C>T p.R337= | Silent (SNP) | VAF 84/206 reads (41%) | catalogued as rs773610849, COSV58668863; called by muse, mutect2, varscan2
- BTN2A1 | c.96C>T p.V32= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as rs768301609; called by muse, mutect2, varscan2
- CASQ2 | c.381C>T p.G127= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as rs775663612, CS117810; called by muse, mutect2, varscan2
- CDH11 | c.1062C>T p.I354= | Silent (SNP) | VAF 60/161 reads (37%) | catalogued as rs771089094, COSV51765224; called by muse, mutect2, varscan2
- CDON | c.846G>A p.P282= | Silent (SNP) | VAF 70/175 reads (40%) | catalogued as rs780286345; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHD7 | c.831G>A p.P277= | Silent (SNP) | VAF 70/173 reads (40%) | catalogued as rs775415630; called by muse, mutect2, varscan2
- COL5A1 | c.291C>T p.P97= | Silent (SNP) | VAF 285/743 reads (38%) | catalogued as rs762823751; called by muse, mutect2, varscan2
- COL9A2 | c.1314C>T p.R438= | Silent (SNP) | VAF 70/188 reads (37%) | catalogued as rs1314555899; called by muse, mutect2, varscan2
- CRELD1 | c.978C>T p.G326= | Silent (SNP) | VAF 75/375 reads (20%) | catalogued as rs374333743; called by muse, mutect2, varscan2
- CSMD1 | c.9885C>T p.F3295= (on ENST00000520002; = p.F3294= on NM_033225.6) | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as rs781556274, COSV59286211; called by muse, mutect2, varscan2
- DCAF8L2 | c.93G>A p.A31= | Silent (SNP) | VAF 112/300 reads (37%) | catalogued as rs768015516; called by muse, mutect2, varscan2
- DENND3 | c.291G>A p.T97= | Silent (SNP) | VAF 143/617 reads (23%) | catalogued as rs574524079, COSV52801082; called by muse, mutect2, varscan2
- DGKZ | c.1545C>T p.F515= (on ENST00000454345 / NM_001105540.2; = p.F327= on NM_003646.4) | Silent (SNP) | VAF 100/254 reads (39%) | catalogued as rs766327652, COSV58992944; called by muse, mutect2, varscan2
- DMD | c.1200A>G p.L400= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as CD098804; called by muse, mutect2, varscan2
- DOCK6 | c.2970C>T p.A990= | Silent (SNP) | VAF 80/205 reads (39%) | catalogued as rs267605282, COSV53920805, COSV99625568; called by muse, mutect2, varscan2
- DPYSL3 | c.1227C>T p.L409= | Silent (SNP) | VAF 42/109 reads (39%) | catalogued as rs779181977, COSV58324268; called by muse, mutect2, varscan2
- EFTUD2 | c.1275C>T p.G425= | Silent (SNP) | VAF 46/183 reads (25%) | called by muse, mutect2, varscan2
- EFTUD2 | c.126C>T p.D42= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as rs751784519, COSV68182342; called by muse, mutect2, varscan2
- EIF4G2 | c.2469C>T p.H823= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs772593462, COSV60597347; called by muse, mutect2, varscan2
- ELP2 | c.1698C>T p.H566= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as rs139251707; called by muse, varscan2
- ENO4 | c.369G>A p.A123= (on ENST00000622726; = p.A122= on NM_001242699.2) | Silent (SNP) | VAF 150/473 reads (32%) | catalogued as rs942093828; called by muse, mutect2, varscan2
- ERBB4 | c.675C>T p.Y225= | Silent (SNP) | VAF 114/256 reads (45%) | catalogued as rs375082554; called by muse, mutect2, varscan2
- FAM214A | c.1251C>T p.N417= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs190376629; called by muse, mutect2, varscan2
- FGF8 | c.405C>T p.I135= (on ENST00000344255 / NM_033164.4; = p.I117= on NM_006119.6) | Silent (SNP) | VAF 311/767 reads (41%) | catalogued as rs767919104, COSV100199357; called by muse, mutect2, varscan2
- FSTL5 | c.1941C>T p.C647= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as rs139415477; called by muse, mutect2, varscan2
- GHDC | c.1317C>T p.Y439= | Silent (SNP) | VAF 65/187 reads (35%) | catalogued as rs756837467, COSV99511543; called by muse, mutect2, varscan2
- GLDN | c.1398G>A p.T466= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs531014922; called by muse, mutect2, varscan2
- HAPLN4 | c.132G>A p.S44= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs769154401; called by muse, mutect2
- HELZ2 | c.4134C>T p.F1378= (on ENST00000467148 / NM_001037335.2; = p.F809= on NM_033405.3) | Silent (SNP) | VAF 163/343 reads (48%) | catalogued as rs116286008; called by muse, mutect2, varscan2
- HELZ2 | c.3144C>T p.G1048= (on ENST00000467148 / NM_001037335.2; = p.G479= on NM_033405.3) | Silent (SNP) | VAF 204/492 reads (41%) | catalogued as rs1411542350; called by muse, mutect2, varscan2
- HMOX2 | c.657C>T p.I219= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs538917494; called by muse, mutect2, varscan2
- HOXC5 | c.231C>T p.S77= | Silent (SNP) | VAF 192/432 reads (44%) | called by muse, mutect2, varscan2
- IL33 | c.525C>T p.D175= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs780716485, COSV67342725; called by muse, mutect2, varscan2
- KATNIP | c.2403C>T p.T801= | Silent (SNP) | VAF 106/465 reads (23%) | catalogued as rs149030906; called by muse, mutect2, varscan2
- KCTD15 | c.804G>A p.P268= | Silent (SNP) | VAF 64/218 reads (29%) | catalogued as rs372373198; called by muse, mutect2, varscan2
- KCTD8 | c.798G>A p.T266= | Silent (SNP) | VAF 113/259 reads (44%) | called by muse, mutect2, varscan2
- KIRREL3 | c.2073C>T p.Y691= | Silent (SNP) | VAF 195/445 reads (44%) | catalogued as rs776552881; called by muse, mutect2, varscan2
- KLHL6 | c.1701C>T p.D567= | Silent (SNP) | VAF 194/563 reads (34%) | catalogued as COSV58067497; called by muse, mutect2, varscan2
- LAMA3 | c.2868C>T p.Y956= | Silent (SNP) | VAF 86/445 reads (19%) | catalogued as rs755080322, COSV58078893; called by muse, mutect2, varscan2
- LDLRAP1 | c.201G>A p.S67= | Silent (SNP) | VAF 162/406 reads (40%) | catalogued as rs747011377; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- LRP1 | c.3408C>T p.D1136= | Silent (SNP) | VAF 135/659 reads (20%) | catalogued as rs143183297; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRC4B | c.1710C>T p.D570= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as COSV65350435; called by muse, mutect2, varscan2
- LRRTM2 | c.171C>T p.N57= | Silent (SNP) | VAF 126/334 reads (38%) | catalogued as rs951766713, COSV51223507; called by muse, mutect2, varscan2
- LTF | c.1176G>A p.S392= | Silent (SNP) | VAF 82/422 reads (19%) | catalogued as rs758871370; called by muse, mutect2, varscan2
- MAG | c.1455C>T p.R485= | Silent (SNP) | VAF 125/312 reads (40%) | catalogued as COSV62701448; called by muse, mutect2, varscan2
- MAN2B1 | c.2154G>A p.P718= | Silent (SNP) | VAF 285/774 reads (37%) | catalogued as rs1239156445; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1770C>T p.T590= | Silent (SNP) | VAF 167/377 reads (44%) | catalogued as rs775229551; called by muse, mutect2, varscan2
- MED16 | c.1038C>T p.N346= | Silent (SNP) | VAF 89/278 reads (32%) | catalogued as rs374459668; called by muse, mutect2, varscan2
- MOV10 | c.1536G>A p.T512= | Silent (SNP) | VAF 103/272 reads (38%) | catalogued as rs754526699, COSV62492489; called by muse, mutect2, varscan2
- MSLNL | c.627C>T p.T209= | Silent (SNP) | VAF 77/174 reads (44%) | catalogued as rs766578454; called by muse, mutect2, varscan2
- NCOR2 | c.6831C>T p.S2277= | Silent (SNP) | VAF 158/529 reads (30%) | catalogued as rs760441945; called by muse, mutect2, varscan2
- NEURL1B | c.1242G>A p.A414= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as rs1189228137; called by muse, mutect2, varscan2
- NLRP2 | c.1008G>A p.T336= | Silent (SNP) | VAF 99/241 reads (41%) | catalogued as rs749628445, COSV54752444, COSV54754349; called by muse, mutect2, varscan2
- NOTCH1 | c.429G>A p.P143= | Silent (SNP) | VAF 539/1312 reads (41%) | catalogued as rs757406877; called by muse, mutect2, varscan2
- NPFFR2 | c.162C>T p.S54= | Silent (SNP) | VAF 157/457 reads (34%) | catalogued as rs576044729, COSV100440245, COSV58149514; called by muse, mutect2, varscan2
- NPY4R | c.378G>A p.T126= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs782100874, COSV65398153; called by mutect2, varscan2
- NR4A2 | c.1131G>A p.P377= | Silent (SNP) | VAF 131/786 reads (17%) | catalogued as rs775946202; called by muse, mutect2, varscan2
- NRXN3 | c.1791C>T p.D597= (on ENST00000557594 / NM_001272020.2; = p.D1021= on NM_004796.6) | Silent (SNP) | VAF 119/363 reads (33%) | catalogued as rs778637260; called by muse, mutect2, varscan2
- NXPE3 | c.1455C>T p.N485= | Silent (SNP) | VAF 65/266 reads (24%) | catalogued as rs763150196; called by muse, mutect2, varscan2
- OGDH | c.1389C>T p.D463= | Silent (SNP) | VAF 64/219 reads (29%) | catalogued as rs923358618; called by muse, mutect2, varscan2
- OR1K1 | c.351G>A p.A117= | Silent (SNP) | VAF 102/288 reads (35%) | catalogued as rs370996319, COSV99474333; called by muse, mutect2, varscan2
- PAPLN | c.2289C>T p.C763= (on ENST00000554301; = p.C736= on NM_173462.4) | Silent (SNP) | VAF 91/219 reads (42%) | catalogued as rs199513457; called by muse, mutect2, varscan2
- PCDH10 | c.243C>T p.R81= | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as rs538631045, COSV52088002; called by muse, mutect2, varscan2
- PCDHA12 | c.1767C>T p.H589= | Silent (SNP) | VAF 301/756 reads (40%) | catalogued as COSV56516535; called by muse, mutect2, varscan2
- PCDHGA1 | c.1695C>T p.P565= | Silent (SNP) | VAF 280/739 reads (38%) | catalogued as rs1168988163, COSV100966068, COSV65296919, COSV65298594; called by muse, mutect2, varscan2
- PCDHGA11 | c.1806C>T p.N602= | Silent (SNP) | VAF 250/653 reads (38%) | called by muse, mutect2, varscan2
- PCDHGB2 | c.1620C>T p.P540= | Silent (SNP) | VAF 407/1006 reads (40%) | catalogued as rs771795005, COSV53961838; called by muse, mutect2, varscan2
- PCK1 | c.474C>T p.I158= | Silent (SNP) | VAF 103/472 reads (22%) | catalogued as rs764002893, COSV60129492; called by muse, mutect2
- PCNX2 | c.2535G>A p.A845= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs372481177; called by muse, mutect2, varscan2
- PCNX4 | c.2619C>T p.N873= (on ENST00000406854 / NM_001330177.2; = p.N639= on NM_022495.5) | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs1343265122; called by muse, mutect2, varscan2
- PDCD6 | c.504C>T p.Y168= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs750895835; called by muse, mutect2, varscan2
- PGBD5 | c.474C>T p.H158= (on ENST00000525115; = p.H227= on NM_001258311.2) | Silent (SNP) | VAF 156/359 reads (43%) | catalogued as rs756094324, COSV58410306, COSV58410659; called by muse, mutect2, varscan2
- PHF2 | c.3273C>T p.N1091= | Silent (SNP) | VAF 57/171 reads (33%) | catalogued as rs745818173, COSV63682804; called by muse, mutect2, varscan2
- PKDREJ | c.5298C>T p.S1766= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs1276062460; called by muse, mutect2, varscan2
- PLEC | c.7062G>A p.T2354= (on ENST00000322810 / NM_201380.4; = p.T2244= on NM_000445.5) | Silent (SNP) | VAF 262/1110 reads (24%) | catalogued as rs782658127; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEKHA6 | c.3099G>A p.S1033= | Silent (SNP) | VAF 189/448 reads (42%) | catalogued as rs777800245, COSV55337614; called by muse, mutect2, varscan2
- POFUT2 | c.786C>T p.D262= | Silent (SNP) | VAF 140/364 reads (38%) | catalogued as rs200720644; called by muse, mutect2, varscan2
- POLG | c.330C>T p.H110= | Silent (SNP) | VAF 266/638 reads (42%) | catalogued as rs376266682, COSV51521536; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- PPP3R2 | c.327C>T p.N109= | Silent (SNP) | VAF 144/361 reads (40%) | catalogued as COSV62450353; called by muse, mutect2, varscan2
- PRDM16 | c.3723C>T p.S1241= | Silent (SNP) | VAF 87/232 reads (38%) | catalogued as rs748391199, COSV54594186; called by muse, mutect2, varscan2
- PRICKLE2 | c.1590G>A p.P530= (on ENST00000295902; = p.P474= on NM_198859.4) | Silent (SNP) | VAF 39/239 reads (16%) | catalogued as rs778956632, COSV99896506; called by muse, mutect2, varscan2
- PRLHR | c.810C>T p.R270= | Silent (SNP) | VAF 139/414 reads (34%) | catalogued as rs774148290; called by muse, mutect2, varscan2
- PRRG3 | c.372C>T p.R124= | Silent (SNP) | VAF 76/216 reads (35%) | catalogued as rs762259905, COSV64851652; called by muse, mutect2, varscan2
- PSME1 | c.606C>T p.H202= | Silent (SNP) | VAF 119/276 reads (43%) | catalogued as rs372568481; called by muse, mutect2, varscan2
- PTGIR | c.441C>T p.C147= | Silent (SNP) | VAF 183/512 reads (36%) | catalogued as rs947845379; called by muse, mutect2, varscan2
- PTK6 | c.108C>T p.H36= | Silent (SNP) | VAF 301/736 reads (41%) | catalogued as rs148206034; called by muse, mutect2, varscan2
- RAB11FIP1 | c.588G>A p.T196= | Silent (SNP) | VAF 56/180 reads (31%) | catalogued as rs377756140, COSV54760595; called by muse, mutect2, varscan2
- RAB9B | c.81C>T p.Y27= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs141822799, COSV54587221; called by muse, mutect2, varscan2
- RAG1 | c.456G>A p.P152= | Silent (SNP) | VAF 50/133 reads (38%) | catalogued as rs368797111, COSV55027077; called by muse, mutect2, varscan2
- RGL3 | c.807C>T p.Y269= | Silent (SNP) | VAF 146/347 reads (42%) | catalogued as rs775121152; called by muse, mutect2, varscan2
- RHBDL1 | c.873C>T p.G291= (on ENST00000219551 / NM_001318733.2; = p.G226= on NM_001278720.2) | Silent (SNP) | VAF 147/321 reads (46%) | catalogued as rs768953134; called by muse, mutect2, varscan2
- RIPOR3 | c.2601C>T p.N867= | Silent (SNP) | VAF 174/520 reads (33%) | catalogued as rs764786515; called by muse, mutect2, varscan2
- RRAD | c.783C>T p.N261= | Silent (SNP) | VAF 304/760 reads (40%) | catalogued as COSV100233598; called by muse, mutect2, varscan2
- S100A5 | c.201C>T p.I67= | Silent (SNP) | VAF 88/246 reads (36%) | catalogued as rs1338630253, COSV63296682; called by muse, mutect2, varscan2
- SCN4A | c.2142C>T p.F714= | Silent (SNP) | VAF 177/482 reads (37%) | catalogued as rs763015471, COSV71129834; called by muse, mutect2, varscan2
- SEC31A | c.2409G>A p.P803= (on ENST00000355196 / NM_001318120.1; = p.P764= on NM_016211.4) | Silent (SNP) | VAF 59/195 reads (30%) | catalogued as rs145039719; called by muse, mutect2, varscan2
- SETD1A | c.3915C>T p.A1305= | Silent (SNP) | VAF 89/296 reads (30%) | catalogued as rs754761866; called by muse, mutect2, varscan2
- SH3TC1 | c.1566G>A p.A522= | Silent (SNP) | VAF 76/168 reads (45%) | catalogued as rs368331401; called by muse, mutect2, varscan2
- SHC3 | c.561C>T p.R187= | Silent (SNP) | VAF 45/164 reads (27%) | catalogued as rs940345621, COSV65440103; called by muse, mutect2, varscan2
- SIM1 | c.606C>T p.D202= | Silent (SNP) | VAF 16/397 reads (4%) | catalogued as rs1180669166, COSV99493010; called by muse, mutect2
- SIRT7 | c.543G>A p.T181= | Silent (SNP) | VAF 226/592 reads (38%) | catalogued as rs1196416245; called by muse, mutect2, varscan2
- SLC30A5 | c.1821C>T p.I607= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1169379826, COSV67448688, COSV67450249; called by muse, mutect2
- SPIB | c.30C>T p.D10= | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as rs778756578, COSV99570206; called by muse, mutect2, varscan2
- SPTBN2 | c.4233C>T p.Y1411= | Silent (SNP) | VAF 326/735 reads (44%) | catalogued as rs151331478; called by muse, mutect2, varscan2
- ST6GAL2 | c.492G>A p.P164= | Silent (SNP) | VAF 150/427 reads (35%) | catalogued as rs1052851126, COSV64530347; called by muse, mutect2, varscan2
- STK32C | c.108G>A p.P36= | Silent (SNP) | VAF 48/106 reads (45%) | called by muse, mutect2, varscan2
- SUMO4 | c.171G>A p.Q57= | Silent (SNP) | VAF 45/90 reads (50%) | catalogued as rs1261453785; called by muse, mutect2, varscan2
- SYT16 | c.1314C>T p.Y438= | Silent (SNP) | VAF 148/464 reads (32%) | catalogued as rs770156483; called by muse, mutect2, varscan2
- TBCCD1 | c.633G>A p.A211= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs372918346; called by muse, mutect2, varscan2
- THSD4 | c.1500G>A p.A500= | Silent (SNP) | VAF 65/178 reads (37%) | catalogued as rs139510947; called by muse, mutect2, varscan2
- TLR9 | c.1845C>T p.A615= | Silent (SNP) | VAF 184/488 reads (38%) | catalogued as rs200242636; called by muse, mutect2, varscan2
- TMC7 | c.1962G>A p.S654= | Silent (SNP) | VAF 85/228 reads (37%) | catalogued as rs752384328; called by muse, mutect2, varscan2
- TNFRSF13B | c.732C>T p.S244= | Silent (SNP) | VAF 58/141 reads (41%) | catalogued as rs371893711; called by muse, mutect2, varscan2
- TP63 | c.255G>A p.A85= | Silent (SNP) | VAF 68/191 reads (36%) | catalogued as rs368463552; ClinVar: likely benign; called by muse, mutect2, varscan2
- TP73 | c.1062G>A p.T354= | Silent (SNP) | VAF 137/328 reads (42%) | catalogued as rs555576629, COSV60699883, COSV60701152; called by muse, mutect2, varscan2
- TRIM42 | c.423G>A p.V141= | Silent (SNP) | VAF 151/336 reads (45%) | called by muse, mutect2, varscan2
- TSPAN10 | c.810C>T p.P270= (on ENST00000574882 / NM_001290212.1; = p.P232= on NM_031945.4) | Silent (SNP) | VAF 412/927 reads (44%) | catalogued as rs756611529; called by muse, mutect2, varscan2
- TTC39A | c.882C>T p.N294= (on ENST00000447632 / NM_001297665.1; = p.N259= on NM_001080494.3) | Silent (SNP) | VAF 123/356 reads (35%) | catalogued as rs1459127659, COSV99396671; called by muse, mutect2, varscan2
- WASF3 | c.1194G>A p.P398= | Silent (SNP) | VAF 122/351 reads (35%) | catalogued as rs1335551343, COSV100099780; called by mutect2, varscan2
- WDFY4 | c.6774C>T p.N2258= | Silent (SNP) | VAF 47/124 reads (38%) | catalogued as rs565938135; called by muse, mutect2, varscan2
- ZAR1L | c.627C>T p.S209= | Silent (SNP) | VAF 40/180 reads (22%) | catalogued as rs762539061, COSV100563891; called by muse, mutect2
- ZBED4 | c.2730C>T p.N910= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs146661762; called by muse, mutect2, varscan2
- ZBTB4 | c.2661C>T p.G887= | Silent (SNP) | VAF 140/363 reads (39%) | catalogued as rs373169784; called by muse, mutect2, varscan2
- ZNF423 | c.273G>A p.T91= (on ENST00000563137 / NM_001379286.1; = p.T83= on NM_015069.4) | Silent (SNP) | VAF 128/390 reads (33%) | catalogued as rs762110313; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF516 | c.2649C>T p.D883= | Silent (SNP) | VAF 128/296 reads (43%) | catalogued as rs763792803, COSV71586769; called by muse, mutect2, varscan2
- ZNF518A | c.2985C>T p.T995= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs112252455; called by muse, mutect2, varscan2
- ABCC3 | c.675-20C>T | Intron (SNP) | VAF 64/157 reads (41%) | catalogued as rs377591319; called by muse, mutect2, varscan2
- ABCG5 | c.143+42G>A | Intron (SNP) | VAF 90/180 reads (50%) | catalogued as rs889161728; called by muse, mutect2, varscan2
- AGPAT4 | c.348+5096G>A | Intron (SNP) | VAF 88/222 reads (40%) | catalogued as rs1228310019, COSV57248024; called by muse, mutect2, varscan2
- ANKRD11 | c.87+3554C>T | Intron (SNP) | VAF 206/486 reads (42%) | catalogued as rs527899878; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1936-35G>A | Intron (SNP) | VAF 47/104 reads (45%) | catalogued as rs771387214; called by muse, mutect2, varscan2
- ATXN7L2 | c.*26G>A | 3'UTR (SNP) | VAF 109/317 reads (34%) | catalogued as rs368096100, COSV100149792; called by muse, mutect2, varscan2
- CDCA5 | c.678+46C>T | Intron (SNP) | VAF 48/135 reads (36%) | catalogued as rs762375035; called by muse, mutect2
- CDKL5 | c.2713+124_2713+125del | Intron (DEL) | VAF 32/116 reads (28%) | called by mutect2, pindel, varscan2
- CFAP74 | c.4654-251G>A | Intron (SNP) | VAF 138/409 reads (34%) | catalogued as rs778301929; called by muse, mutect2, varscan2
- COL16A1 | c.-3G>A | 5'UTR (SNP) | VAF 129/434 reads (30%) | catalogued as rs761709105, COSV99594992; called by muse, mutect2, varscan2
- COPS9 | chr2:240129963 G>A | 3'Flank (SNP) | VAF 190/557 reads (34%) | catalogued as rs374935553; called by muse, mutect2, varscan2
- DDX11 | c.881-72C>T | Intron (SNP) | VAF 114/334 reads (34%) | called by muse, varscan2
- DIP2C | c.85+38562G>A | Intron (SNP) | VAF 104/281 reads (37%) | catalogued as rs1267148470; called by muse, mutect2, varscan2
- FGR | c.226+70C>T | Intron (SNP) | VAF 99/245 reads (40%) | catalogued as rs979779856; called by muse, mutect2, varscan2
- FMO6P | n.933C>T | RNA (SNP) | VAF 15/53 reads (28%) | catalogued as rs199867331; called by muse, mutect2, varscan2
- FREM1 | c.4857+1715C>T | Intron (SNP) | VAF 20/35 reads (57%) | catalogued as rs367829739; called by muse, mutect2, varscan2
- FRMD1 | c.384+261C>T | Intron (SNP) | VAF 108/353 reads (31%) | catalogued as rs763607730; called by muse, mutect2, varscan2
- HSPA7 | n.745C>T | RNA (SNP) | VAF 121/548 reads (22%) | called by muse, mutect2, varscan2
- IGLV2-33 | c.-20G>A | 5'UTR (SNP) | VAF 97/360 reads (27%) | catalogued as rs767619302; called by muse, mutect2, varscan2
- KDM6B | c.*43C>T | 3'UTR (SNP) | VAF 64/148 reads (43%) | called by muse, mutect2, varscan2
- LINC00174 | n.3764G>A | RNA (SNP) | VAF 71/351 reads (20%) | catalogued as rs757018830; called by muse, mutect2
- MDS2 | n.426C>T | RNA (SNP) | VAF 24/61 reads (39%) | catalogued as rs1280351117; called by muse, mutect2, varscan2
- MEMO1 | c.438-1119G>A | Intron (SNP) | VAF 11/21 reads (52%) | catalogued as rs773896566; called by muse, mutect2, varscan2
- MPRIP | c.2163+4739G>A | Intron (SNP) | VAF 31/111 reads (28%) | catalogued as rs560323745, COSV100506137; called by muse, mutect2, varscan2
- MRPL55 | c.27-182C>T | Intron (SNP) | VAF 53/139 reads (38%) | catalogued as rs763406280, COSV99686749; called by muse, mutect2, varscan2
- NRG3 | c.823+1831G>A | Intron (SNP) | VAF 9/64 reads (14%) | catalogued as rs572733630, COSV64559102; called by muse, mutect2, varscan2
- PDZD4 | c.296+418G>A | Intron (SNP) | VAF 111/250 reads (44%) | catalogued as rs1328037056; called by muse, mutect2, varscan2
- PKD1 | c.11411+25G>A | Intron (SNP) | VAF 406/1029 reads (39%) | catalogued as rs1207683239; called by muse, mutect2, varscan2
- PTBP3 | chr9:112220291 C>T | 3'Flank (SNP) | VAF 24/90 reads (27%) | catalogued as rs759409115, COSV57580653; called by muse, mutect2, varscan2
- SLC52A3 | c.1198-49C>T | Intron (SNP) | VAF 32/83 reads (39%) | catalogued as rs777394360, COSV99447833; called by muse, mutect2, varscan2
- SUPT20HL2 | c.-556C>T | 5'UTR (SNP) | VAF 151/458 reads (33%) | catalogued as rs776466813; called by muse, varscan2
- SYP | c.*4+11G>A | Intron (SNP) | VAF 247/676 reads (37%) | catalogued as rs1219958595; called by muse, mutect2, varscan2
- TAZ | c.-111G>A | 5'UTR (SNP) | VAF 408/940 reads (43%) | catalogued as rs1557190588; called by muse, mutect2, varscan2
- TFAP2A | c.*44C>T | 3'UTR (SNP) | VAF 114/272 reads (42%) | called by muse, mutect2, varscan2
- TRIM8 | c.*379C>T | 3'UTR (SNP) | VAF 41/118 reads (35%) | catalogued as rs772349788, COSV100193475; called by muse, mutect2, varscan2
- ZNF662 | c.-94+208G>A | Intron (SNP) | VAF 106/270 reads (39%) | called by muse, mutect2, varscan2
